Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3317, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3317-01A (Primary Tumor).

[page 1 of 2]
Laboratory Patient Report
Print Date/Time:

Surgical Pathology

Histopathological Examination

Path#:
Collected: Received: Complete:

Pre-Op Diagnosis : Left Renal Mass

Order Physician

Specimens : Kidney, Left

Frozen Diagnosis :

Report

: GROSS EXAMINATION.

The specimen is received in a container labeled with the name of the patient and labeled as kidney, left. The specimen consists of a kidney and attached perinephric fat which measures en bloc 24 x 14 x 10 cm and weighs 1709 g. The ureter and vascular margins of resection are submitted in block 1. The lower pole and midportion of the kidney shows a large golden yellow mass measuring 12.0 x 9.0 x 7.0 cm. The mass grossly bulges against the capsule and is focally adherent to the capsule. Sections of the capsule adjacent to the mass are submitted in block 2. The kidney stripped of capsule and fat measures 13.5 x 11.0 x 7.0 cm and weighs 542 g. Sections of the mass are submitted in block 3-8. Sections of the renal sinus are submitted in blocks 9-10. The pelvis and calices are not grossly dilated. The cortex averages 0.7 cm. A random section of kidney is submitted in block 11. Sectioning through the attached fat shows an adrenal gland measuring 8.0 x 2.5 x 1.5 cm. Representative sections are submitted in block 12.

MICROSCOPIC EXAMINATION:

Multiple sections of kidney shows a renal cell carcinoma with clear cell features, moderately well-differentiated consistent with a Fuhrman grade 2 forming a tumor mass that by description measures up to 12 cm greatest diameter. Sections of the capsule show no apparent adherence of the tumor to the capsule or in the surrounding pericapsular adipose tissue. Both the ureter and vascular margins are free of tumor. No definite blood vessel invasion by the tumor could be seen. Section of the area of the renal sinus is negative for tumor and the pelvis of the kidney and bordering ureter is also negative.

[page 2 of 2]
DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

Left kidney, radical nephrectomy, left: Renal cell carcinoma, clear cell type, Fuhrman grade 2, 12 cm greatest diameter.

No invasion of capsule, no blood vessel invasion identified with ureter and vascular margin of resection free of tumor. Renal sinus free of tumor.

Adrenal gland, benign.

Pathologic stage: pT2,NX,MX provisional stage II.

[T-71000 M-83103 189.0 P3-44070]

Electronically Signed by:

Source: NCI Genomic Data Commons file 801f14f8-8bbb-4e95-b781-5a1f0b9b1bdf (TCGA-A3-3317.94C1E956-19F6-49A2-A524-9553A0FD7B3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).